Somatic mutation profile of tumor specimen TCGA-XU-AAXX-01A (aliquot TCGA-XU-AAXX-01A-11D-A428-09) from TCGA case TCGA-XU-AAXX, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymoma, type B2, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 44.5 years (16,265 days).
Specimen TCGA-XU-AAXX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 462b33c1-4fd7-475b-9a03-92c2458299ea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XU-AAXX-10A (Blood Derived Normal), aliquot TCGA-XU-AAXX-10A-01D-A42B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b46471a1-b6d7-45e5-b128-96e9d1791476

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDX4 | c.1880G>T p.R627L | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61755946; called by muse, mutect2
